Somatic mutation profile of tumor specimen TCGA-FE-A23A-01A (aliquot TCGA-FE-A23A-01A-11D-A17V-08) from TCGA case TCGA-FE-A23A, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 27.9 years (10,177 days).
Specimen TCGA-FE-A23A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ba9fc6c-94ab-4416-969f-5b18932794ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A23A-10A (Blood Derived Normal), aliquot TCGA-FE-A23A-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bd3edd2-9742-4540-8a58-8f857fe6237e

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARHGAP4 | c.422G>C p.R141P | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100604070, COSV63134642; called by muse, mutect2, varscan2
- CD109 | c.3932G>A p.S1311N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV54656938; called by muse, mutect2, varscan2
- HNRNPH2 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57267459; called by muse, mutect2, varscan2
- IRF3 | c.601+1G>A p.X201_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV55864606; called by muse, mutect2, varscan2
- OR4L1 | c.119T>A p.M40K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV59851258; called by muse, mutect2, varscan2
- CIAPIN1 | c.75G>A p.L25= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV67953346, COSV67953534; called by muse, mutect2, varscan2
